Gene-level copy-number profile of tumor specimen TCGA-22-1016-01A from TCGA case TCGA-22-1016, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.9 years (24,078 days).
Specimen TCGA-22-1016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d1e6d4e3-b89a-40bd-8f71-615bedc47b00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-1016-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2960ff76-d318-48d6-9a01-320312034cfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,997; copy number 2: 28,543; copy number 3: 10,711; copy number 4: 12,354; copy number 5: 3,627; copy number 6: 96; copy number 7: 235; copy number 8: 119; copy number 10: 8; copy number 11: 31; copy number 13: 16; copy number 16: 23; copy number 27: 34; copy number 39: 7; copy number 50: 1; copy number 55: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-1016-01A-01D-0685-01): tumor purity 0.33, ploidy 2.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,207 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,059,837–51,798,427, 22 genes, copy number 16: MIR4421, MIR6500, C1orf185, Y_RNA, CFL1P2, LINC01562, RNF11, AL162430.1, AL162430.2, TTC39A, TTC39A-AS1, EPS15, AL671986.1, RNU6-877P, AC104170.1, EPS15-AS1, RNU6-1281P, CALR4P, OSBPL9, GAPDHP51, SLC25A6P3, AL050343.1.
- chr1:51,793,934–51,799,154, 1 gene, copy number 16: AL050343.2.
- chr1:52,633,168–53,051,698, 18 genes, copy number 7 (within-gene range 2–7): SHISAL2A, COA7, NDUFS5P3, RN7SL62P, ZYG11B, RNU2-30P, RPS13P2, RNU6-969P, ZYG11A, AC099677.3, ECHDC2, AC099677.1, AC099677.2, SCP2, AC099677.4, AC099677.6, AC099677.5, H3P2.
- chr1:53,180,921–54,225,464, 40 genes, copy number 7: AL606760.4, CPT2, AL606760.2, CZIB, AL606760.3, MAGOH, AL606760.1, LRP8, AL355483.3, AL355483.1, AL355483.2, LINC01771, AC119428.2, AC119428.1, LINC02812, SLC25A3P1, AL365445.1, DMRTB1, GLIS1, RNU7-95P, NDC1, AL049745.1, AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37.
- chr1:54,236,440–54,239,063, 1 gene, copy number 7: SSBP3-AS1.
- chr1:54,974,900–56,524,495, 23 genes, copy number 10–13 (within-gene range 4–13): AL590440.2, TMEM61, AL590440.1, BSND, PCSK9, USP24, MIR4422HG, GYG1P3, MIR4422, AL603840.1, GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA, LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767.
- chr1:69,055,838–102,389,630, 502 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr1:237,042,184–237,833,988, 1 gene, copy number 5 (within-gene range 4–5): RYR2.
- chr1:237,471,119–241,364,054, 56 genes, copy number 5: MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1.
- chr2:54,456,317–99,490,035, 932 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:218,162,841–222,656,092, 129 genes, copy number 7–11 (broad region; genes not listed).
- chr3:151,425,384–198,222,513, 817 genes, copy number 5 (broad region; genes not listed).
- chr4:71,741,696–78,008,688, 122 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–4,440,259, 96 genes, copy number 6–8 (broad region; genes not listed).
- chr5:7,373,115–10,440,388, 71 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:38,556,765–38,671,216, 1 gene, copy number 7 (within-gene range 4–7): LIFR-AS1.
- chr5:38,682,070–41,587,787, 39 genes, copy number 7: AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1.
- chr5:52,579,555–54,415,238, 30 genes, copy number 6: MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25.
- chr6:89,433,152–91,816,428, 30 genes, copy number 5: ANKRD6, RN7SL11P, AL159174.1, LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7, AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1.
- chr6:92,013,842–92,014,734, 1 gene, copy number 5: RPL5P19.
- chr8:46,028,804–48,931,288, 61 genes, copy number 8 (broad region; genes not listed).
- chr8:140,636,281–141,786,313, 27 genes, copy number 6: ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7.
- chr10:58,999,482–60,733,490, 17 genes, copy number 6 (within-gene range 3–6): LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2.
- chr11:101,451,564–103,479,863, 52 genes, copy number 27–55 (within-gene range 2–55): TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr14:83,750,384–103,503,831, 491 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:30,214,765–53,875,557, 626 genes, copy number 5 (broad region; genes not listed).
- chr20:53,940,160–53,942,508, 1 gene, copy number 5: AC005220.1.

Autosomal genes at a single copy (total copy number 1): 3,955. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
